Gene-level copy-number profile of tumor specimen TCGA-05-4398-01A from TCGA case TCGA-05-4398, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 47.8 years (17,471 days).
Specimen TCGA-05-4398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c161a99e-9aa9-4ab1-9c6c-2c2be2308f85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4398-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7642a87-a3a1-4e25-a24d-908319f48187

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 503; copy number 2: 3,629; copy number 3: 8,298; copy number 4: 16,374; copy number 5: 18,096; copy number 6: 3,742; copy number 7: 2,479; copy number 8: 1,434; copy number 9: 2,528; copy number 10: 311; copy number 11: 1,385; copy number 12: 304; copy number 13: 526; copy number 15: 103; copy number 21: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4398-01A-01D-1204-01): tumor purity 0.33, ploidy 4.83, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:59,821,040–60,198,172, 13 genes: AC098847.1, PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P, AC090771.2, RPS3AP49, RNU4-17P, AC090771.1.
- chr18:60,495,868–62,587,709, 30 genes (within-gene range 0–4): AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,379 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,646,230–152,720,470, 113 genes, copy number 12 (broad region; genes not listed).
- chr2:140,586,626–141,208,376, 6 genes, copy number 11: MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:157,210,847–158,682,879, 23 genes, copy number 13 (within-gene range 9–13): CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22.
- chr2:163,152,251–165,392,310, 18 genes, copy number 12 (within-gene range 8–12): RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3.
- chr2:187,001,876–187,556,288, 4 genes, copy number 13 (within-gene range 7–13): IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P.
- chr5:35,429,064–36,876,700, 28 genes, copy number 12: U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr7:70,972–62,275,678, 1,079 genes, copy number 11 (broad region; genes not listed).
- chr7:88,749,470–103,074,843, 357 genes, copy number 11–13 (within-gene range 10–13) (broad region; genes not listed).
- chr7:106,090,505–108,995,029, 50 genes, copy number 11: SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:127,652,194–134,066,589, 156 genes, copy number 13 (within-gene range 8–13) (broad region; genes not listed).
- chr8:70,608,577–81,924,348, 182 genes, copy number 13–21 (within-gene range 6–21) (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 13: LINC02839.
- chr12:1,791,963–1,918,666, 1 gene, copy number 11 (within-gene range 7–11): CACNA2D4.
- chr12:1,917,951–7,976,360, 216 genes, copy number 11 (broad region; genes not listed).
- chr19:32,830,509–35,813,299, 145 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 503. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
